Somatic mutation profile of tumor specimen TARGET-15-SJMPAL041122-09A.2 (aliquot TARGET-15-SJMPAL041122-09A.2-01D) from TARGET case TARGET-15-SJMPAL041122, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.3 years (486 days).
Specimen TARGET-15-SJMPAL041122-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 807fba33-bf84-4053-a108-26c1d29fd9e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL041122-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL041122-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87f330dd-bdbe-47e4-a0d2-bb2c69ddf0cb

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Splice Region 2, Frame Shift Del 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MACROD2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs557866799, COSV54026962; called by muse, mutect2, varscan2
- MFNG | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747879329; called by muse, mutect2, varscan2
- NUCB1 | c.660C>A p.N220K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV99617651; called by muse, mutect2, varscan2
- ADGRA3 | c.1372del p.M458Wfs*9 | Frame Shift Del (DEL) | VAF 25/59 reads (42%) | called by mutect2, varscan2
- CHD6 | c.5090G>T p.S1697I | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); called by muse, mutect2
- HDX | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.136); called by mutect2, varscan2
- HSPB6 | c.321G>T p.P107= | Splice Region (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- KDM5B | c.1824G>T p.L608= | Splice Region (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- KLK9 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PRPSAP1 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.106); called by muse, mutect2
- SPI1 | c.443_444insGCCCAATG p.E149Pfs*40 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | called by pindel, varscan2
- AREL1 | c.489G>T p.V163= | Silent (SNP) | VAF 4/25 reads (16%) | called by mutect2, varscan2
- FLACC1 | c.1248A>G p.E416= | Silent (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- HMMR | c.24G>A p.L8= | Silent (SNP) | VAF 44/86 reads (51%) | called by muse, mutect2, varscan2
- LINC01001 | n.317C>A | RNA (SNP) | VAF 4/31 reads (13%) | called by muse, varscan2
